Somatic mutation profile of tumor specimen TCGA-F4-6854-01A (aliquot TCGA-F4-6854-01A-11D-1924-10) from TCGA case TCGA-F4-6854, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.4 years (28,272 days).
Specimen TCGA-F4-6854-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76b279dc-0d94-49e9-bb3a-d40784033e51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6854-10A (Blood Derived Normal), aliquot TCGA-F4-6854-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/578fc202-d252-444b-964c-fe76bed3e3ce

The open-access MAF lists 125 somatic variants for this specimen: 99 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 25, Nonsense Mutation 8, Frame Shift Ins 3, Frame Shift Del 2, Splice Region 1, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA4 | c.1064G>C p.R355T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1035193409, COSV100933257; called by muse, mutect2, varscan2
- ADGRA3 | c.2221G>T p.A741S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV51568305; called by muse, mutect2
- AJAP1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs987473812, COSV65450439; called by muse, mutect2, varscan2
- ANKRD1 | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as COSV63311209; called by muse, mutect2, varscan2
- ANO2 | c.1738A>G p.T580A (on ENST00000356134 / NM_001278597.3; = p.T584A on NM_001278596.3) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59043188; called by muse, mutect2, varscan2
- APOB | c.6717C>A p.N2239K | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99268202; called by muse, mutect2, varscan2
- ASPM | c.3922G>T p.A1308S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as COSV54132685, COSV99661158; called by muse, mutect2
- ATAD5 | c.4516T>A p.F1506I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs762173043, COSV58979092; called by muse, varscan2
- ATAD5 | c.4517T>A p.F1506Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV58979101; called by muse, varscan2
- ATAD5 | c.4518T>A p.F1506L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV58979113; called by muse, varscan2
- ATOH1 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV60038746; called by muse, mutect2, varscan2
- ATP10B | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59164601; called by muse, mutect2, varscan2
- ATRX | c.7064C>T p.S2355L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV64871658; called by muse, mutect2, varscan2
- BANK1 | c.1314A>C p.E438D | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV59849826; called by muse, mutect2, varscan2
- BCL9 | c.1409_1416del p.I470Tfs*9 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as COSV52350064; called by mutect2, pindel, varscan2
- CACNA1E | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV100705447; called by muse, mutect2, varscan2
- CATSPER1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs543744984, COSV56408716; called by muse, mutect2, varscan2
- CCN3 | c.274A>T p.S92C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV52385384; called by muse, mutect2, varscan2
- CFAP69 | c.1762T>A p.L588M | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60188402; called by muse, mutect2, varscan2
- CHD3 | c.5760C>A p.Y1920* (on ENST00000330494 / NM_001005273.3; = p.Y1886* on NM_005852.4) | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV57880260; called by muse, mutect2, varscan2
- CHRNB3 | c.809C>A p.S270* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | catalogued as COSV51493271, COSV51497886; called by muse, mutect2, varscan2
- COL10A1 | c.1525C>A p.P509T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV54573523, COSV99684480; called by muse, mutect2
- COL24A1 | c.2681G>T p.G894V | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65314127; called by muse, mutect2, varscan2
- COL5A2 | c.2752G>T p.G918* | Nonsense Mutation (SNP) | VAF 16/238 reads (7%) | catalogued as COSV100880841; called by muse, mutect2
- DLGAP1 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV59835207; called by muse, mutect2, varscan2
- DNAH5 | c.5776G>T p.E1926* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV54202729, COSV99454399; called by muse, mutect2, varscan2
- DSCAM | c.1604T>A p.I535N | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68036043; called by muse, mutect2, varscan2
- DUSP16 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53809802; called by muse, mutect2, varscan2
- DZIP1 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as rs1289924797, COSV61264212, COSV61269544; called by muse, mutect2, varscan2
- EEFSEC | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs758326257, COSV99631470; called by mutect2, varscan2
- FCGBP | c.4598C>T p.P1533L | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs1206633245, COSV99664191; called by muse, mutect2, varscan2
- FRG2B | c.375dup p.S126Ifs*11 | Frame Shift Ins (INS) | VAF 28/118 reads (24%) | catalogued as rs1157131073; called by pindel, varscan2
- FRMD7 | c.1447T>G p.C483G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV53748822; called by muse, mutect2, varscan2
- FSIP2 | c.17268A>C p.K5756N | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV58099515; called by muse, mutect2, varscan2
- G6PD | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782674059, COSV63704386; called by muse, mutect2, varscan2
- GCC1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200271393; called by muse, mutect2, varscan2
- GLE1 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs749111923, COSV59410597; called by muse, mutect2, varscan2
- GRID1 | c.2849A>G p.N950S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as COSV60052891; called by muse, mutect2, varscan2
- GSE1 | c.2513C>T p.T838M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs546647649, COSV53675995; called by muse, mutect2, varscan2
- H4C12 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100694731, COSV100694760, COSV100694763; called by muse, mutect2, varscan2
- HELZ2 | c.4572G>A p.M1524I (on ENST00000467148 / NM_001037335.2; = p.M955I on NM_033405.3) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV71297012; called by muse, mutect2, varscan2
- HERC5 | c.2634G>T p.K878N | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV52044942; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1411194835, COSV99404532; called by muse, mutect2, varscan2
- IGSF10 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372867906; called by muse, mutect2, varscan2
- IGSF9B | c.2039C>A p.T680K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.262); catalogued as COSV58072422, COSV58072776; called by muse, mutect2, varscan2
- INKA2 | c.326G>T p.R109M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV61879063; called by muse, mutect2, varscan2
- KIAA1109 | c.4727C>A p.S1576* | Nonsense Mutation (SNP) | VAF 8/155 reads (5%) | catalogued as COSV99176793; called by muse, mutect2
- KLK13 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs200725984; called by muse, mutect2, varscan2
- LRBA | c.1543A>G p.M515V | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.094); catalogued as COSV63964830; called by muse, mutect2
- LRP2 | c.259T>G p.C87G | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790340; called by muse, mutect2, varscan2
- LRRC7 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV60567980; called by muse, mutect2, varscan2
- LY75 | c.3311C>T p.A1104V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55113038; called by muse, mutect2, varscan2
- MAGEA6 | c.240G>T p.W80C | Missense Mutation (SNP) | VAF 83/127 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100263000; called by muse, mutect2, varscan2
- MAGEA6 | c.239G>T p.W80L | Missense Mutation (SNP) | VAF 83/125 reads (66%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100262998; called by muse, mutect2, varscan2
- MEF2A | c.425T>C p.V142A (on ENST00000557942 / NM_001319206.2; = p.V144A on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100573976; called by muse, varscan2
- MIIP | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs143726942; called by muse, mutect2, varscan2
- MRGPRX2 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61674970; called by muse, mutect2, varscan2
- MYH8 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs780695842, COSV67972423; called by muse, mutect2, varscan2
- N4BP2 | c.2387C>T p.T796I | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV99789302; called by muse, mutect2, varscan2
- NALCN | c.4843G>A p.E1615K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.288); catalogued as rs756729162, COSV51939252; called by muse, mutect2, varscan2
- NDUFAF7 | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV50018893; called by muse, mutect2, varscan2
- NLRP7 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as COSV60181865; called by muse, mutect2, varscan2
- OBSCN | c.7742T>C p.L2581P | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99484500; called by muse, mutect2, varscan2
- OR5R1 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100393597; called by muse, mutect2, varscan2
- PCDHA6 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs1554131892, COSV67076271; called by muse, mutect2, varscan2
- PCDHGB3 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV99547362; called by muse, mutect2, varscan2
- PCLO | c.15145T>A p.L5049I | Missense Mutation (SNP) | VAF 104/177 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100434877, COSV61665816; called by muse, mutect2, varscan2
- PCLO | c.13488G>T p.R4496S | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758487913, COSV61660870; called by muse, mutect2, varscan2
- PIK3R3 | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.035); catalogued as COSV53111230; called by muse, mutect2, varscan2
- PLOD1 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.492); catalogued as COSV52150404; called by muse, mutect2, varscan2
- PTPRK | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV63907065; called by muse, mutect2, varscan2
- RBMXL2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs148341004; called by muse, mutect2, varscan2
- ROR2 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV65223461; called by muse, mutect2
- SETD1A | c.2435G>T p.R812L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52692433; called by muse, mutect2, varscan2
- SFMBT1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.62); catalogued as rs1206001338, COSV56255628; called by muse, mutect2, varscan2
- SNRNP70 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55507392; called by muse, mutect2, varscan2
- SPART | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766680187, COSV62088013; called by muse, mutect2, varscan2
- SRCAP | c.6940C>T p.R2314C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745546363, COSV52674817; called by muse, mutect2, varscan2
- STAC | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs764073834, COSV56218110; called by muse, mutect2, varscan2
- SUPT20HL2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 81/122 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs747276547; called by muse, mutect2, varscan2
- TAF1A | c.920A>C p.H307P | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61919962; called by muse, mutect2, varscan2
- TCERG1L | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1298657845, COSV64048422, COSV64057584; called by muse, mutect2, varscan2
- TTC21B | c.1892G>T p.G631V | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV54635172; called by muse, mutect2, varscan2
- TTLL5 | c.2602+1G>A p.X868_splice | Splice Site (SNP) | VAF 5/66 reads (8%) | catalogued as rs867401129, COSV100089722; called by muse, mutect2
- TTN | c.88277G>A p.S29426N (on ENST00000591111; = p.S22002N on NM_003319.4) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | PolyPhen benign (0.021); catalogued as COSV60076780; called by muse, mutect2, varscan2
- VWA1 | c.423G>C p.W141C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100100814; called by muse, mutect2
- VWCE | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57115421; called by muse, mutect2, varscan2
- ZDHHC1 | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100799514; called by muse, mutect2, varscan2
- ZNF500 | c.1073G>A p.C358Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54789978; called by muse, mutect2, varscan2
- ARID1A | c.3229dup p.A1077Gfs*28 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- ARMC4 | c.568A>T p.I190F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); called by muse, mutect2
- CSNK2A1 | c.842G>A p.W281* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- MUC5B | c.2197_2202del p.T733_C734del | In Frame Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, pindel, varscan2
- SETX | c.6058dup p.I2020Nfs*4 | Frame Shift Ins (INS) | VAF 26/88 reads (30%) | called by mutect2, varscan2
- SPATA1 | c.948C>T p.A316= | Splice Region (SNP) | VAF 15/43 reads (35%) | called by mutect2, varscan2
- TMEM104 | c.1342del p.D448Tfs*197 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- ABCA7 | c.801C>T p.C267= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs755393286, COSV54037309; called by muse, mutect2
- ATP8B3 | c.1719G>A p.T573= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1469594481, COSV59543166; called by muse, mutect2, varscan2
- C1QTNF5 | c.27C>G p.L9= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1283376665, COSV60991512; called by muse, mutect2
- CEACAM21 | c.87C>T p.N29= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs545179785, COSV51815274; called by muse, mutect2, varscan2
- CHD5 | c.4198C>T p.L1400= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99315110; called by muse, mutect2, varscan2
- CHUK | c.1293G>A p.V431= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100957278; called by muse, varscan2
- CPA1 | c.774C>T p.D258= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs368689434; called by muse, mutect2, varscan2
- EPHB1 | c.1989G>A p.R663= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV67656997; called by muse, mutect2, varscan2
- HARS2 | c.534C>T p.D178= | Silent (SNP) | VAF 49/154 reads (32%) | catalogued as rs1266947372, COSV51227540; called by muse, mutect2, varscan2
- HAS2 | c.1035C>T p.L345= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV58267160; called by muse, mutect2, varscan2
- KIAA1217 | c.1950G>A p.R650= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1026039870, COSV56823770; called by muse, mutect2, varscan2
- KIF3B | c.1527C>T p.I509= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV65229327; called by muse, mutect2, varscan2
- KRT1 | c.1818C>T p.G606= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV52867675; called by muse, mutect2, varscan2
- MAML3 | c.2496C>T p.N832= | Silent (SNP) | VAF 41/62 reads (66%) | catalogued as rs371995834; called by muse, mutect2, varscan2
- MCM7 | c.1425C>T p.L475= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV57998878; called by muse, mutect2, varscan2
- MEP1A | c.1044T>C p.Y348= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV57922526; called by muse, mutect2, varscan2
- NCR1 | c.675C>A p.T225= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV52558525; called by muse, mutect2, varscan2
- PAPPA | c.759C>T p.I253= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs759429627, COSV60277248; called by muse, mutect2, varscan2
- PCSK5 | c.2448G>A p.Q816= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV65096477, COSV65098197; called by muse, mutect2, varscan2
- PGLYRP2 | c.876C>T p.P292= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV52997863; called by muse, mutect2, varscan2
- PKDREJ | c.1806T>C p.D602= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV53553143; called by muse, mutect2, varscan2
- PSG5 | c.915C>T p.N305= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs550647828, COSV61655375; called by muse, mutect2
- SDK2 | c.1677G>A p.T559= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs756114813, COSV101167075, COSV66196714; called by muse, mutect2, varscan2
- TUBGCP2 | c.780G>A p.V260= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV53308762; called by muse, mutect2, varscan2
- ZNF254 | c.555A>G p.K185= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as rs781087276, COSV61644840; called by muse, mutect2, varscan2
- ATAT1 | c.108-204G>A | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs1307797487, COSV52542586; called by muse, mutect2, varscan2
